Somatic mutation profile of tumor specimen MMRF_2456_1_BM_CD138pos (aliquot MMRF_2456_1_BM_CD138pos_T1_KHS5U_L11595) from MMRF case MMRF_2456, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.6 years (25,793 days).
Specimen MMRF_2456_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fa56ae0-1e7b-4882-abda-44086cd298aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2456_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2456_1_PB_Whole_C3_KHS5U_L11596; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fe3b768-a4e5-4dae-9c72-6ab5cad31c30

The open-access MAF lists 151 somatic variants for this specimen: 76 protein-altering or splice-affecting, 20 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, 3'UTR 25, Silent 20, Intron 14, 5'UTR 7, Nonsense Mutation 5, Frame Shift Del 4, 3'Flank 4, 5'Flank 3, Splice Site 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2626C>T p.Q876* | Nonsense Mutation (SNP) | VAF 65/84 reads (77%) | catalogued as COSV65952959; called by muse, mutect2, varscan2
- ATM | c.1517G>A p.G506D | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV53747416; called by muse, mutect2
- CCDC174 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775202853; called by muse, mutect2, varscan2
- CDH13 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as rs377371675; called by muse, mutect2, varscan2
- DBR1 | c.737C>G p.A246G | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99604515; called by muse, mutect2, varscan2
- DMRT2 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV52404133; called by muse, mutect2, varscan2
- DST | c.8315T>G p.F2772C | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV55001807; called by muse, mutect2, varscan2
- ELAVL2 | c.206A>C p.K69T | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774235866; called by muse, mutect2, varscan2
- EPS15L1 | c.2363G>A p.R788Q | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50172689; called by muse, mutect2, varscan2
- FBXO9 | c.1299C>A p.F433L | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55055366; called by muse, mutect2, varscan2
- FFAR1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 104/225 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.397); catalogued as rs778277031, COSV50070531; called by muse, mutect2, varscan2
- GFPT2 | c.214+5G>A | Splice Region (SNP) | VAF 29/144 reads (20%) | catalogued as COSV99517777; called by muse, mutect2, varscan2
- GRM5 | c.2500C>T p.R834C | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1471625539, COSV59597532; called by muse, mutect2, varscan2
- H1-4 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs200686576, COSV56800958; called by muse, mutect2, varscan2
- HR | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs139885496; called by muse, mutect2, varscan2
- HSD17B13 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as COSV56347010; called by muse, mutect2, varscan2
- IGHD6-6 | c.12C>G p.S4R | Missense Mutation (SNP) | VAF 57/101 reads (56%) | PolyPhen probably damaging (0.986); catalogued as rs529699011; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.65A>T p.Q22L | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1418295249; called by muse, mutect2
- KIF14 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1558097027; called by muse, mutect2, varscan2
- KRT27 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs762368035; called by muse, mutect2, varscan2
- LOXHD1 | c.4922C>T p.A1641V | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs992296929, COSV56062658, COSV56065874; called by muse, mutect2, varscan2
- LRRTM1 | c.783G>T p.M261I | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54439519; called by muse, mutect2, varscan2
- MGAT4B | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs1421956194, COSV52978104; called by muse, mutect2
- NYAP2 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774975681, COSV56009066; called by muse, mutect2, varscan2
- PCF11 | c.1421C>T p.S474L | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs569738550, COSV100018716; called by muse, mutect2, varscan2
- PRR14 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1252267145, COSV99788548; called by muse, mutect2
- RERE | c.3005C>T p.A1002V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as rs1360471285; called by muse, mutect2, varscan2
- SDCCAG8 | c.958G>C p.V320L | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV59416825; called by muse, mutect2, varscan2
- SHANK1 | c.3719C>A p.A1240D | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV99520241; called by muse, mutect2, varscan2
- SLC25A5 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100510530; called by muse, mutect2, varscan2
- SLC4A11 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66263118; called by muse, mutect2, varscan2
- SLIRP | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs564243588; called by muse, mutect2, varscan2
- STYK1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs200398907; called by muse, mutect2, varscan2
- VPS35 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 17/103 reads (17%) | catalogued as rs1341452806; called by muse, mutect2, varscan2
- ZHX1 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.368); catalogued as COSV52877994; called by muse, mutect2, varscan2
- ZSCAN20 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773355618; called by muse, mutect2, varscan2
- ACKR4 | c.77A>C p.Q26P | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.043); called by muse, mutect2
- ADAMTS16 | c.2415G>C p.W805C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APAF1 | c.2353_2354del p.Q785Vfs*24 (on ENST00000551964 / NM_181861.2; = p.Q774Vfs*24 on NM_001160.3) | Frame Shift Del (DEL) | VAF 69/238 reads (29%) | called by mutect2, pindel, varscan2
- ATXN1L | c.1630C>G p.P544A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRD1 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.268); called by muse, mutect2
- COL15A1 | c.1783T>C p.S595P | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- DBR1 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DDX3X | c.1846C>T p.R616C (on ENST00000399959; = p.R617C on NM_001356.5) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DNAJC2 | c.1684_1685del p.L562Gfs*13 | Frame Shift Del (DEL) | VAF 133/428 reads (31%) | called by mutect2, pindel, varscan2
- FASTKD3 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAT4 | c.4132C>G p.L1378V | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2
- GYG1 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 131/386 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- HS3ST3A1 | c.866G>C p.G289A | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- IFITM1 | c.241A>T p.T81S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- IGDCC4 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- IGHV2-70D | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, varscan2
- KRTAP4-7 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- LARS1 | c.2737C>A p.L913I (on ENST00000394434 / NM_020117.11; = p.L886I on NM_016460.3) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- LHFPL5 | c.413-1G>C p.X138_splice | Splice Site (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- LRRN3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAP3K19 | c.2917C>G p.L973V | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MARK1 | c.806T>A p.V269D | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- MTBP | c.1250T>G p.L417W | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MYO9A | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSMAF | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- PAPPA2 | c.2869T>A p.F957I | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- PENK | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PWWP3A | c.1443_1447del p.D481Efs*34 (on ENST00000627377; = p.D480Efs*34 on NM_032853.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- RTTN | c.6353T>G p.L2118* | Nonsense Mutation (SNP) | VAF 138/304 reads (45%) | called by muse, mutect2, varscan2
- SP140 | c.1359_1363del p.K453Nfs*21 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- TBC1D8B | c.616T>A p.S206T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (1); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- THEMIS | c.1553A>G p.N518S | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNFSF10 | c.190T>A p.Y64N | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- TRHR | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 103/289 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TRIM49B | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- TRIO | c.157+2T>C p.X53_splice | Splice Site (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- TRPM8 | c.977G>T p.C326F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WHAMM | c.1368G>C p.L456F | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ZMYM4 | c.1303A>G p.I435V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ZNF462 | c.5189T>A p.L1730* | Nonsense Mutation (SNP) | VAF 58/306 reads (19%) | called by muse, mutect2, varscan2
- ATXN7 | c.789G>A p.P263= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as rs372476262; called by muse, mutect2
- CELSR1 | c.1521C>T p.F507= | Silent (SNP) | VAF 49/239 reads (21%) | called by muse, mutect2, varscan2
- CFAP46 | c.7350G>A p.S2450= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs767038292; called by muse, mutect2, varscan2
- COL5A3 | c.93T>G p.P31= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs924625344; called by muse, mutect2, varscan2
- ELP3 | c.1362C>G p.R454= | Silent (SNP) | VAF 49/159 reads (31%) | called by muse, mutect2, varscan2
- H4C11 | c.273C>T p.L91= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as rs750050019, COSV61826938; called by muse, mutect2
- HSPA12A | c.1821C>T p.H607= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as rs200665425, COSV65020713; called by muse, mutect2, varscan2
- IGLV3-22 | c.345A>G p.S115= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as rs1243813387; called by muse, mutect2, varscan2
- KIF26B | c.2613C>T p.N871= | Silent (SNP) | VAF 123/468 reads (26%) | catalogued as rs373165733; called by muse, mutect2, varscan2
- LAPTM4B | c.600C>T p.I200= (on ENST00000445593; = p.I109= on NM_018407.6) | Silent (SNP) | VAF 25/311 reads (8%) | called by muse, mutect2
- LTBP3 | c.1326C>T p.R442= | Silent (SNP) | VAF 110/343 reads (32%) | called by muse, mutect2, varscan2
- MYOF | c.5964C>T p.D1988= | Silent (SNP) | VAF 76/184 reads (41%) | catalogued as rs543062400; called by muse, varscan2
- NKD2 | c.267C>T p.D89= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as rs750111447, COSV56891820; called by muse, varscan2
- OR4C12 | c.219T>C p.S73= | Silent (SNP) | VAF 62/175 reads (35%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1785C>T p.R595= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as rs1554120080; called by muse, mutect2, varscan2
- RIIAD1 | c.99T>C p.I33= | Silent (SNP) | VAF 163/289 reads (56%) | called by muse, mutect2, varscan2
- SEMA3C | c.1140A>T p.G380= | Silent (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- SERPINB6 | c.426T>C p.F142= (on ENST00000612421 / NM_001271823.2; = p.F123= on NM_004568.6) | Silent (SNP) | VAF 36/285 reads (13%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.1212C>T p.L404= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1413342004; called by muse, mutect2, varscan2
- ZNF484 | c.1803T>C p.I601= | Silent (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- ACVR2B | c.-72C>T | 5'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- ADGRE2 | chr19:14731377 C>T | 3'Flank (SNP) | VAF 8/19 reads (42%) | catalogued as rs768125740; called by muse, mutect2, varscan2
- ADGRL3 | chr4:62072258 T>G | 3'Flank (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- ADH1B | c.567+43_567+44del | Intron (DEL) | VAF 110/338 reads (33%) | called by mutect2, pindel, varscan2
- ALDH3A2 | c.1443+1175A>C | Intron (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- ARF5 | chr7:127591962 C>T | 3'Flank (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- ARHGAP28 | c.2030+1962G>A | Intron (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- ARMCX4 | c.1038+1510G>A | Intron (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- ATP11C | c.*1102G>A | 3'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- BTG2 | c.*493_*500delinsG | 3'UTR (DEL) | VAF 14/92 reads (15%) | called by pindel, varscan2*
- C10orf67 | c.*1540T>A | 3'UTR (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- CA5AP1 | n.169C>T | RNA (SNP) | VAF 35/324 reads (11%) | called by muse, mutect2, varscan2
- CALML5 | c.-116G>T | 5'UTR (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2
- CAMLG | c.*19G>A | 3'UTR (SNP) | VAF 75/246 reads (30%) | called by muse, mutect2, varscan2
- CLCN2 | c.-77G>A | 5'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- COL11A1 | c.*295_*296del | 3'UTR (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- COL21A1 | c.*1052T>G | 3'UTR (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- DENND4C | c.2734+39C>T | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as rs1303785806; called by muse, mutect2, varscan2
- DNAJB4 | c.*350A>T | 3'UTR (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- DPH2 | c.*650A>G | 3'UTR (SNP) | VAF 11/47 reads (23%) | catalogued as COSV52544511; called by muse, mutect2, varscan2
- DYNLT3 | chrX:37836869 T>G | 3'Flank (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- FAM110C | c.*2682G>A | 3'UTR (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- FAM13B | c.*298A>T | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- FBXO33 | c.*1183A>C | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- FIBIN | c.*587del | 3'UTR (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- FSTL4 | c.*1166G>A | 3'UTR (SNP) | VAF 20/146 reads (14%) | catalogued as rs933268007; called by muse, mutect2, varscan2
- FSTL5 | c.*360del | 3'UTR (DEL) | VAF 44/110 reads (40%) | catalogued as rs1191175476; called by mutect2, varscan2
- GNG11 | c.-17C>T | 5'UTR (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2
- GUCY1B1 | c.*594T>A | 3'UTR (SNP) | VAF 42/144 reads (29%) | called by muse, mutect2, varscan2
- KCNK9 | chr8:139702999 C>A | 5'Flank (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- LBHD1 | c.616+1217A>T | Intron (SNP) | VAF 46/116 reads (40%) | called by mutect2, varscan2
- LINC01583 | n.258C>T | RNA (SNP) | VAF 90/225 reads (40%) | called by muse, mutect2, varscan2
- LPP | c.*15230C>T | 3'UTR (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- LPXN | c.-64C>T | 5'UTR (SNP) | VAF 10/298 reads (3%) | called by muse, mutect2
- MICALL1 | c.*45C>G | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- MYLK | c.3652+148C>T | Intron (SNP) | VAF 10/21 reads (48%) | catalogued as rs1449794870; called by muse, mutect2, varscan2
- NTN4 | c.585+69del | Intron (DEL) | VAF 32/74 reads (43%) | catalogued as rs372779502; called by mutect2, varscan2
- OPA3 | c.-34A>T | 5'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- PAPPA | c.*4605A>G | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- PCLO | c.14791+186T>A | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- PLOD2 | chr3:146163618 del T | 5'Flank (DEL) | VAF 182/466 reads (39%) | called by mutect2, varscan2
- RBBP9 | c.*2211T>C | 3'UTR (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- SATB1 | c.-24-396T>C | Intron (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- SEMA3A | c.*1637A>T | 3'UTR (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- SGO2 | c.703+132A>G | Intron (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.*207G>A | 3'UTR (SNP) | VAF 25/217 reads (12%) | called by muse, mutect2, varscan2
- SIX4 | c.*1033A>T | 3'UTR (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- SLC25A4 | c.-84C>T | 5'UTR (SNP) | VAF 5/51 reads (10%) | catalogued as rs183128370; called by muse, mutect2
- SPRN | c.*489A>G | 3'UTR (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- TMEM232 | n.1012-9353T>C | Intron (SNP) | VAF 24/68 reads (35%) | catalogued as rs1348200595; called by muse, mutect2, varscan2
- TPRKB | c.265-33C>G | Intron (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- TRIM29 | c.1705-1066C>T | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- TRMT9B | c.*971G>A | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331209 G>A | 5'Flank (SNP) | VAF 9/27 reads (33%) | catalogued as rs1265586536; called by mutect2, varscan2
- USP46 | c.*2733G>A | 3'UTR (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
